Gene-level copy-number profile of tumor specimen TCGA-C5-A0TN-01A from TCGA case TCGA-C5-A0TN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 21.2 years (7,760 days).
Specimen TCGA-C5-A0TN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.e7a33b84-8a6a-4aba-befa-59ffde38bdb4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A0TN-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/49d97515-9704-464a-b5ef-f5e957954f6a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 14,139; copy number 2: 40,317; copy number 3: 5,170; copy number 4: 21; copy number 6: 16; copy number 8: 17; copy number 10: 68; copy number 11: 11; copy number 28: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A0TN-01A-21D-A14V-01): tumor purity 0.89, ploidy 1.81, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 172 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:95,482,406–109,583,907, 172 genes, copy number 6–28 (within-gene range 1–28) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,139. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
